Surgical pathology report (de-identified scan), TCGA case TCGA-28-5215, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5215-01A (Primary Tumor).

[page 1 of 5]
Patient: [REDACTED]

Accession Number: [REDACTED]

Hospital No: [REDACTED]

Pathologist: [REDACTED]

Ordering M.D.: [REDACTED]

Date of Birth: [REDACTED]

Assistant: [REDACTED]

Age/Sex: [REDACTED]

Date of Procedure: [REDACTED]

Copies To: [REDACTED]

Date Received: [REDACTED]

TCGA-28-5215

Location: [REDACTED]

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV ✓

B. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

C. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI#1:

- Glioblastoma multiforme, WHO grade IV ✓
- 3% of tumor necrosis
- 95% of tumor cellularity

D. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI#2:

- Glioblastoma multiforme, WHO grade IV
- 20% of tumor necrosis
- 95% of tumor cellularity

E. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI#3:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

F. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI#4:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity

G. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI#5:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

H. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI#6:

- Glioblastoma multiforme, WHO grade IV
- 1% of tumor necrosis
- 95% of tumor cellularity

IDC2a: Selected slides were reviewed in consultation with [REDACTED]

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to [REDACTED]. Hence, the 20% result in this case suggests the possibility of a relatively diminished response to [REDACTED] ✓

Patient Case(s) [REDACTED]

Copy For [REDACTED]

Page 1 of 5

PATIENT NOTIFIED OF RESULTS		
DR:	NURSE:	DATE:

[page 2 of 5]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****

ACCESSION #: [REDACTED]

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

[REDACTED] Association between laminin-8 and glial tumor grade, recurrence, and patient survival. [REDACTED]

Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme [REDACTED]

Cancer Res. [REDACTED]

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case may predict a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

Preoperative diagnosis: Right temporal tumor ✓

MICROSCOPIC FINDINGS:

This focally necrotizing diffusely infiltrating astrocytoma is composed of pleomorphic hyperchromatic angulate nuclei associated with numerous mitotic figures, and endothelial proliferation. Focally prominent myxoid matrix is also detected.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
MGMT	B3	20%
PTEN	B3	Loss (1+)
pMAPK	B3	60% of tumor nuclei and 70% of cytoplasm is positive
Laminin beta 1 (8/411)	B3	Up-regulated (3+ in endothelial cells and staining in the large fraction of tumor cells)
Laminin beta 2 (9/421)	B3	Focal loss of expression (1+ with paranuclear retention)
EGFR	B3	Pending

GROSS:

A. RIGHT TEMPORAL LOBE

Labeled with the patient's name, labeled "right temporal lobe", and received in formalin is a 6.3 x 3.7 x 1.8 cm irregular portion of the temporal lobe. Along the outer aspect the gyri and sulci are within normal caliber. The cut surface reveals soft gray-brown tissue with pinpoint areas of hemorrhage. Entirely submitted. ✓

Slide key:

A1-A24. 1 each

[page 3 of 5]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****

ACCESSION #: [REDACTED]

B. RIGHT TEMPORAL TUMOR FSA

Labeled with the patient's name, labeled "right temporal tumor", and received fresh from intraoperative consultation and subsequently submitted in formalin is a 2.8 x 2.4 x 0.4 cm aggregate of soft hemorrhagic pale tan-brown tissue. Entirely submitted.

Slide key:

B1. Frozen remnant #1 - 1

B2. Frozen remnant #2 - 1

B3, B4. Remaining tissue - Multiple each

C. RIGHT TEMPORAL LOBE NCI#1

Labeled with the patient's name, labeled "right temporal lobe" and received in formalin are two pieces of soft pale tan-brown tissue measuring 0.3 and 0.5 cm in greatest dimension. Entirely submitted.

Slide key:

C1. 2

D. RIGHT TEMPORAL LOBE NCI#2

Labeled with the patient's name, labeled "right temporal lobe" and received in formalin are two pieces of soft pale tan-brown tissue measuring 0.3 and 0.5 cm in greatest dimension. Entirely submitted.

Slide key:

D1. 2

E. RIGHT TEMPORAL LOBE NCI#3

Labeled with the patient's name, labeled "right temporal lobe" and received in formalin are two pieces of soft pale tan-brown tissue measuring 0.3 and 0.5 cm in greatest dimension. Entirely submitted.

Slide key:

E1. 2

F. RIGHT TEMPORAL LOBE NCI#4

Labeled with the patient's name, labeled "right temporal lobe" and received in formalin are two pieces of soft pale tan-brown tissue measuring 0.3 and 0.5 cm in greatest dimension. Entirely submitted.

Slide key:

F1. 2

G. RIGHT TEMPORAL LOBE NCI#5

Labeled with the patient's name, labeled "right temporal lobe" and received in formalin are two pieces of soft pale tan-brown tissue measuring 0.3 and 0.5 cm in greatest dimension. Entirely submitted.

Slide key:

G1. 2

H. RIGHT TEMPORAL LOBE NCI#6

Labeled with the patient's name, labeled "right temporal lobe" and received in formalin are two pieces of soft pale tan-brown tissue measuring 0.3 and 0.5 cm in greatest dimension. Entirely submitted.

Slide key:

H1. 2

Gross dictated by [REDACTED]

[page 4 of 5]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****

ACCESSION #: [REDACTED]

INTRAOPERATIVE CONSULTATION: [REDACTED]
OPERATIVE CALL
OPERATIVE CONSULT (FROZEN):

- A) RIGHT TEMPORAL LOBE TUMOR, FSA + TPA
- High grade glioma consistent with glioblastoma multiforme

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in BRAIN

Tissue Block: [REDACTED]

RESULTS: POLYSOMY of chromosome 7 (See note below)

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed. The control sample gave expected results.

These studies showed polysomy of chromosome 7 in 45% of the nuclei examined. In brain tumors this signal pattern correlates with an amplified EGFR signal pattern.

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $<40\%$ of the cells.

References:

[REDACTED]
These FISH tests were developed and their performance characteristics determined by [REDACTED] as required by the CLIA [REDACTED] regulations. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

[page 5 of 5]
PATIENT:

***** Addendum - Please See End of Report *****

ACCESSION #:

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file a46c3d4a-6f55-4f19-b7fb-44490731b913 (TCGA-28-5215.3A06F0A3-5EB6-4FEF-948B-8067976886E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).